CCDI case PBCLPP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/f2a4dd2c-7280-4408-aa0a-e89b07a80dc5

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 1.5 years (565 days).

Biospecimens (1 sample)
- Sample 0DW2W5: Tissue type: Tumor; Specimen type: Solid Tissue.
